Gene-level copy-number profile of tumor specimen ALCH-B2QD-TTP1-A from ALCHEMIST case ALCH-B2QD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.6 years (29,075 days).
Specimen ALCH-B2QD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96463cfa-4bcb-4513-8402-eca2f5c567b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2QD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/00afaa2b-ecce-47c9-9ded-34dc22922195

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,087; copy number 2: 45,799; copy number 3: 7,722; copy number 4: 772; copy number 5: 1; copy number 6: 7.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,720,312–15,786,594, 5 genes (within-gene range 0–2): AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1.
- chr7:5,306,790–5,513,809, 9 genes (within-gene range 0–2): TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:78,666,089–78,719,765, 1 gene, copy number 5 (within-gene range 3–5): ZC2HC1A.
- chr9:61,190,003–61,453,030, 7 genes, copy number 6: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.

Autosomal genes at a single copy (total copy number 1): 4,087. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
